Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IM, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IM-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT OBTURATOR LYMPH NODES:
Three lymph nodes, no tumor present. (0/3).
- (B) LEFT OBTURATOR LYMPH NODES:
Two lymph nodes, no tumor present. (0/2)
- (C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

CGCF ICD-O-3
path Adenocarcinoma, acinar 8140/3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 11/24/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) RIGHT OBTURATOR LYMPH NODES – Multiple pieces of irregularly shaped yellow-tan adipose measuring 6.2 x 2.5 x 1.0 cm. Three potential lymph nodes are found, ranging in size from 1.0 to 4.1 cm in greatest dimension.
SECTION CODE: A1, A2, one lymph node in each cassette, bisected; A3-A5, single largest lymph node, serially sectioned.
- (B) LEFT OBTURATOR LYMPH NODES – Multiple pieces of yellow-tan adipose measuring 4.5 x 4.0 x 1.0 cm. Specimen is palpated to reveal three potential lymph nodes, ranging in size from 0.7 to 2.2 cm in greatest dimension.
SECTION CODE: B1, single lymph node; B2, B3, single lymph node, serially sectioned; B4, B5, single largest lymph node, serially sectioned.
- (C) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 3]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(C) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3). (SEE COMMENT)

TUMOR CONFINED TO THE PROSTATE.

MARGINS OF RESECTION FREE OF TUMOR.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH-GRADE.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

COMMENT

The prostate gland contains three foci of prostatic adenocarcinoma, two in the peripheral zone and one in the transition zone. The dominant tumor focus is located in the left lateral and left posterolateral peripheral zone. This tumor focus measures 1.0 x 0.8 cm in the largest cross-sectional dimension and it is present in three cross sections, focally in the apex and extensively in the base region. The second tumor focus is located in the right lateral and right posterolateral peripheral zone. This tumor focus measures 0.6 x 0.2 cm in the largest cross-sectional dimension and it is present in two cross sections and focally in the apical region. The third tumor focus is located in the right transition zone. This tumor focus measures 0.3 x 0.2 cm in the largest cross sectional dimension and it is present in one cross section and focally in the base region.

All tumor foci are confined to the prostate. The margins of resection are free of tumor.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES - A prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.4 x 3.3 x 2.7 cm, 31.0 gm, post fixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate appears more abundant than along the left side. A nodule is palpated in the left base region. Serial cross sections after fixation demonstrative a firm area consistent with tumor in the left posterolateral peripheral zone of the three cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

Also included in the container is a portion of tissue (1.8 x 0.9 x 0.5 cm) consistent with seminal vesicle.

SECTION CODE: C1, C2, detached portion of tissue; C3-C5, right seminal vesicle and segment of right vas deferens from the base towards the tip; C6-C8, left seminal vesicle and segment of left vas deferens from the base towards the tip; C9, C10, prostatic base right border; C11, C12, prostatic base, right posterior border; C13-C18, prostatic base central portion; C19, C20, prostatic base left border; C21, C22, prostatic base left posterior border; C23, C24, apex anterior; C25, C26, apex left; C27, C28, apex posterior; C29-C31, apex right; C32-C43, sections of the three cross sections of the prostate according to specimen radiograph.

[page 3 of 3]
Accession: [REDACTED]

Specimen Date/Time: [REDACTED]

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (C29-C31, 34, 38 and 42) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 401662e7-3fa6-4ff2-a984-e101b3b505bf (TCGA-KK-A8IM.C0D3148F-A371-4983-9E62-DA5446385173.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).